Gene-level copy-number profile of tumor specimen TCGA-VQ-A8DU-01A from TCGA case TCGA-VQ-A8DU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 63.1 years (23,042 days).
Specimen TCGA-VQ-A8DU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.dd92248e-f696-4d30-bc93-fa7385afd572.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8DU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5802977-1938-447d-b42d-4ef2cde4d1dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 2,940; copy number 2: 29,935; copy number 3: 16,828; copy number 4: 8,165; copy number 5: 912; copy number 6: 858; copy number 7: 21; copy number 8: 51; copy number 17: 12; copy number 20: 71; copy number 23: 2; copy number 68: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8DU-01A-11D-A363-01): tumor purity 0.58, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,026,698–117,027,039, 1 gene: PTMAP8.
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr5:60,459,848–60,548,813, 5 genes: SETP21, AC109486.2, PART1, AC109486.3, AC016591.1.
- chr16:78,525,189–78,553,296, 3 genes: AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,931 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,848,276–9,910,336, 1 gene, copy number 5 (within-gene range 3–5): CTNNBIP1.
- chr1:9,900,614–10,472,529, 26 genes, copy number 5: AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1.
- chr1:204,154,819–204,728,106, 21 genes, copy number 5 (within-gene range 4–5): REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr1:234,565,298–235,161,283, 24 genes, copy number 6: AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr1:235,190,034–235,190,116, 1 gene, copy number 6: MIR4753.
- chr3:101,940,859–101,997,926, 3 genes, copy number 5: LINC02085, Y_RNA, AC106712.1.
- chr5:58,198–45,895,970, 710 genes, copy number 6–8 (broad region; genes not listed).
- chr6:30,617,840–30,989,903, 33 genes, copy number 5: MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21.
- chr6:106,629,578–106,668,417, 1 gene, copy number 68 (within-gene range 4–68): QRSL1.
- chr6:106,695,535–106,975,627, 5 genes, copy number 23–68: LINC02526, LINC02532, RNU6-117P, MIR587, CD24.
- chr7:68,640,798–71,713,600, 17 genes, copy number 5 (within-gene range 3–5): AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1, GALNT17, MIR3914-1, MIR3914-2.
- chr9:128,039,135–128,361,470, 20 genes, copy number 5: AL360268.2, NAIF1, SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1, LCN2, C9orf16, CIZ1, DNM1, MIR199B, MIR3154, GOLGA2, SWI5, TRUB2, AL359091.3, COQ4, SLC27A4, TMSB4XP4.
- chr11:61,496,440–61,747,001, 10 genes, copy number 5 (within-gene range 3–5): AP003108.1, MIR4488, LRRC10B, SYT7, AP003108.5, AP003559.1, AP002754.1, RPLP0P2, AP002754.2, DAGLA.
- chr11:69,371,463–69,704,022, 10 genes, copy number 6: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19.
- chr17:39,603,536–40,565,472, 53 genes, copy number 5: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7.
- chr17:48,045,141–49,086,702, 65 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–832,469, 30 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1.
- chr18:6,729,716–8,406,861, 20 genes, copy number 5 (within-gene range 1–5): ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1.
- chr18:22,647,582–23,260,467, 10 genes, copy number 7: RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1.
- chr18:23,257,164–23,260,354, 1 gene, copy number 7: AC011731.1.
- chr19:23,525,631–23,874,701, 10 genes, copy number 7 (within-gene range 2–7): ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3.
- chr19:27,638,483–32,719,595, 100 genes, copy number 8–20 (broad region; genes not listed).
- chr20:24,237,255–46,364,458, 540 genes, copy number 5–8 (broad region; genes not listed).
- chr20:50,081,124–50,321,342, 11 genes, copy number 8: UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:57,957,126–64,313,132, 209 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,929. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
